Surgical pathology report (de-identified scan), TCGA case TCGA-ZC-AAAH, project TCGA-THYM (Thymoma), tissue source site  University of Mannheim, specimen TCGA-ZC-AAAH-01A (Primary Tumor).

ICD-O 3
Thymoma, type B2, malignant
Site Anterior mediastinum C38.1
path
Mediastinum NOS C38.3
JW 3/12/14

Original report:

Macroscopy:

9.5x7.5x3.5cm measuring, 90g tissue. In lamellar cut surfaces a 5.5x4.5x2cm large lobulated, partially turned perfused tumor with gray-white surface.

- 1.1: Frozen section.
- 1.2: vascular surgical margins in the region of the right thymus
- 1.3 : Right thymus cranial
- 1.4 : Right-sided mediastinal pleura
- 1.5-7 : Left -sided thymus with bleeding
- 1.8 : Left-sided mediastinal pleura .
- 1.9-1.10: Ventral preparation shares.
- 1.11: dorsal preparation shares
- 1.12-15 : More cuts

Microscopy:

Histologically, a lobular, focal regressive tumour in a normal developed thymus. Small - to large - lobular up the tumour and rich of epithelial cells, but consistently dominated by lymphoid cells. It is noteworthy that also occur within the tumour follicles. The normal thymus shows a moderate thymitis with some germinal centers.

Assessment:

In summary, the thymoma shows the image of a WHO type B2 thymoma, in some sections, also a B1 thymoma (about 60:40). In the present material with infiltration of mediastinal fat (Masaoka stage II) and intratumorous lymphofollicular hyperplasia. The thymoma extends below the pleura, without real infiltration.

Short report:

Date of tumour procurement:

Anatomic site:

Mediastinum

Final diagnosis:

Thymoma WHO-typ B2 (60%), some areas type B1 (40%) // the tissue for TCGA only contains the B2-parts

Discrepancy between histology on frozen section and paraffin section:

None

Source: NCI Genomic Data Commons file 133b1047-03ba-41c2-948b-9b0fc1d5afa2 (TCGA-ZC-AAAH.F8070912-ADA4-4A22-8DE2-4AA7F1B906C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).